Somatic mutation profile of tumor specimen ALCH-AENH-TTP1-A (aliquot ALCH-AENH-TTP1-A-2-0-D-A627-36) from ALCHEMIST case ALCH-AENH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.6 years (25,431 days).
Specimen ALCH-AENH-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f90a74f0-041a-4ddc-9243-d208afc2383b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AENH-NB1-A (Blood Derived Normal), aliquot ALCH-AENH-NB1-A-2-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/801790e3-af58-48a8-a9ee-c5f3fefc2823

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 5, 5'UTR 3, Nonsense Mutation 1, RNA 1, Intron 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 22/228 reads (10%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ETS2 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs775434582, COSV62872833; called by muse, mutect2
- LEUTX | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs751166546; called by muse, mutect2
- MBD1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780948760, COSV53273071; called by muse, mutect2, varscan2
- NAV3 | c.4859C>T p.A1620V | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV57084636; called by muse, mutect2
- PIK3R5 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52656613; called by muse, mutect2
- RASSF8 | c.183A>G p.I61M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as COSV51452555; called by muse, mutect2, varscan2
- USP25 | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.138); catalogued as rs1469457645; called by muse, mutect2
- ZC3H13 | c.2356C>G p.R786G | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV54456741; called by muse, mutect2
- ZNF224 | c.1748T>G p.L583R | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs773741468; called by muse, mutect2
- ANO1 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CEP68 | c.1921C>G p.L641V | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CLDN10 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 51/415 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- DNAJC16 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2
- GAS2L3 | c.1512A>C p.K504N | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2AJ1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PNISR | c.1714_1715del p.R572Efs*2 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | called by mutect2, pindel
- SELENOS | c.214C>G p.P72A | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.391); called by muse, varscan2
- SETDB1 | c.2744A>T p.D915V | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); called by muse, mutect2
- STXBP5L | c.1379A>T p.Y460F | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2
- TNR | c.2249A>G p.Y750C | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- URI1 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 40/344 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- WASHC2C | c.3445A>C p.K1149Q (on ENST00000336378; = p.K1128Q on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/1198 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2
- ZNF497 | c.1115A>G p.N372S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- ATP2A3 | c.2121C>T p.D707= | Silent (SNP) | VAF 17/184 reads (9%) | catalogued as rs140563350; called by muse, mutect2
- KLB | c.2787T>C p.Y929= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs758585283; called by muse, mutect2
- NR1I2 | c.1194C>T p.T398= | Silent (SNP) | VAF 57/550 reads (10%) | catalogued as rs769978712, COSV51769965; called by muse, mutect2, varscan2
- RGS22 | c.2686C>A p.R896= | Silent (SNP) | VAF 26/262 reads (10%) | catalogued as rs772854946, COSV62660241; called by muse, mutect2, varscan2
- TTBK2 | c.2151A>G p.T717= | Silent (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- AC098591.2 | n.1206G>A | RNA (SNP) | VAF 35/238 reads (15%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812024 G>A | 3'Flank (SNP) | VAF 11/162 reads (7%) | catalogued as rs575073221; called by muse, mutect2
- GNG2 | c.-40C>T | 5'UTR (SNP) | VAF 48/308 reads (16%) | called by muse, mutect2, varscan2
- KANK3 | c.-14C>T | 5'UTR (SNP) | VAF 26/219 reads (12%) | called by muse, mutect2, varscan2
- LY6G6D | c.179-19G>A | Intron (SNP) | VAF 22/460 reads (5%) | called by muse, mutect2
- PIGK | c.-1C>T | 5'UTR (SNP) | VAF 61/353 reads (17%) | catalogued as rs1157213436; called by muse, mutect2, varscan2
